Somatic mutation profile of tumor specimen TCGA-17-Z050-01A (aliquot TCGA-17-Z050-01A-01W-0747-08) from TCGA case TCGA-17-Z050, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z050-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96355b5c-9ac0-4b1e-ac66-41e145f4778e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z050-11A (Solid Tissue Normal), aliquot TCGA-17-Z050-11A-01W-0747-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25f0bd27-2eda-447f-bd38-3752780bbf06

The open-access MAF lists 179 somatic variants for this specimen: 132 protein-altering or splice-affecting, 45 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 45, Nonsense Mutation 7, Frame Shift Del 4, Splice Site 3, Intron 1, 3'UTR 1, Splice Region 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLEC14A | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 19/120 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV60564301; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 22/46 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.7565T>C p.I2522T | Missense Mutation (SNP) | VAF 47/426 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs753393467; called by muse, mutect2, varscan2
- ADAMTS17 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as rs553814602; called by muse, varscan2
- AGAP3 | c.2159C>T p.A720V (on ENST00000622464; = p.A756V on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV68243444; called by muse, mutect2, varscan2
- APBB2 | c.1118C>T p.A373V (on ENST00000295974 / NM_001166050.2; = p.A374V on NM_004307.2) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.905); catalogued as COSV55954653; called by muse, varscan2
- APOB | c.866A>G p.E289G | Missense Mutation (SNP) | VAF 50/384 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs372790791; called by mutect2, varscan2
- ASCL3 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748424739, COSV57941056; called by muse, mutect2, varscan2
- CCDC180 | c.4696C>T p.R1566C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747488703; called by muse, mutect2, varscan2
- CCL23 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as rs761784343; called by muse, mutect2, varscan2
- CDH9 | c.2309G>T p.W770L | Missense Mutation (SNP) | VAF 122/579 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1342748030, COSV104370355; called by muse, mutect2, varscan2
- CLMN | c.1546G>T p.A516S | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as rs1393640344; called by muse, mutect2, varscan2
- DLG2 | c.2347C>T p.R783W | Missense Mutation (SNP) | VAF 53/303 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373589966, COSV54622296; called by muse, mutect2, varscan2
- EPS15L1 | c.2467G>T p.D823Y | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs768437608; called by muse, varscan2
- FLG2 | c.1835G>C p.R612T | Missense Mutation (SNP) | VAF 65/558 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV101165838; called by muse, mutect2, varscan2
- FOXN3 | c.259G>T p.V87F | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs61754094; called by muse, mutect2, varscan2
- FPGT | c.626G>A p.S209N | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.481); catalogued as rs1301828149; called by muse, mutect2, varscan2
- GPR156 | c.560A>G p.D187G | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59938216; called by muse, mutect2
- HEATR5A | c.5516C>A p.T1839K | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV66344904; called by mutect2, varscan2
- HSD17B4 | c.430A>T p.I144F (on ENST00000414835 / NM_001199291.3; = p.I119F on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs777276125; called by muse, mutect2
- ITGAX | c.3145G>T p.G1049C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51652142; called by muse, mutect2, varscan2
- KCNK13 | c.1171del p.V391Wfs*7 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | catalogued as rs766469179, COSV56415804; called by pindel, varscan2
- KIAA1109 | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.879); catalogued as COSV52696899; called by muse, mutect2, varscan2
- LDLR | c.1718G>T p.G573V | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as CD108088; called by muse, mutect2, varscan2
- MMP12 | c.1276G>T p.G426W | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58261585; called by muse, mutect2, varscan2
- MS4A10 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57632801; called by muse, mutect2, varscan2
- MTG1 | c.986dup p.A330Gfs*2 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | catalogued as rs770677100; called by pindel, varscan2
- MYO9A | c.7231C>A p.P2411T | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs1229494594; called by muse, mutect2, varscan2
- NLRP3 | c.955G>T p.D319Y | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as COSV60221853; called by mutect2, varscan2
- OR2T33 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.938); catalogued as rs754408140; called by muse, mutect2, varscan2
- OR4D10 | c.844C>T p.L282F | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV73259985; called by muse, mutect2, varscan2
- OR51F1 | c.44C>A p.T15K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV58580820; called by muse, mutect2
- PCDHGA2 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.499); catalogued as rs750919254, COSV53939307; called by muse, mutect2, varscan2
- PFKM | c.1471C>T p.Q491* | Nonsense Mutation (SNP) | VAF 33/292 reads (11%) | catalogued as rs1399694963; called by muse, mutect2, varscan2
- PIWIL1 | c.718G>T p.D240Y | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV55346274; called by muse, mutect2
- PSG7 | c.875A>T p.N292I | Missense Mutation (SNP) | VAF 81/653 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as COSV101343316; called by muse, mutect2, varscan2
- PURG | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415911015; called by muse, mutect2, varscan2
- RAB27B | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs749824892; called by muse, mutect2, varscan2
- RAB38 | c.8C>A p.A3D | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV54712181; called by muse, mutect2, varscan2
- RESF1 | c.4592A>G p.N1531S | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs1203077476; called by muse, mutect2, varscan2
- RYR1 | c.3298C>A p.R1100S | Missense Mutation (SNP) | VAF 53/357 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV62088699; called by muse, mutect2, varscan2
- SEL1L | c.2332C>T p.R778W | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.798); catalogued as rs769333290; called by muse, varscan2
- SERPINB5 | c.804G>T p.K268N | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV66975417; called by muse, mutect2, varscan2
- SLITRK1 | c.382G>T p.G128W | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99058295; called by muse, mutect2
- SMC4 | c.368T>C p.I123T | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771547168; called by muse, mutect2, varscan2
- THEG | c.797C>G p.S266W | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV61074578; called by mutect2, varscan2
- TMEM132E | c.1928A>G p.Y643C (on ENST00000321639; = p.Y733C on NM_001304438.2) | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs766279007; called by muse, mutect2, varscan2
- TRIM58 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100825164; called by muse, mutect2, varscan2
- TULP4 | c.631G>T p.G211C | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764504122, COSV65573043; called by muse, mutect2, varscan2
- USP51 | c.1591G>C p.E531Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.745); catalogued as COSV72351566, COSV72351626; called by muse, mutect2, varscan2
- VCAN | c.2261C>A p.T754K | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV54108135, COSV99424941; called by mutect2, varscan2
- VMP1 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 65/621 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.465); catalogued as COSV51864345, COSV99031686; called by muse, mutect2, varscan2
- ZNF449 | c.887G>C p.G296A | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.883); catalogued as rs781880838; called by muse, mutect2, varscan2
- ZNF532 | c.3070G>T p.G1024W | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755735875; called by muse, mutect2, varscan2
- ZSCAN4 | c.1037A>G p.Q346R | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs1163660820; called by muse, mutect2, varscan2
- ARFIP2 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ARMC3 | c.1045A>T p.S349C | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- ASTN2 | c.1819G>T p.E607* (on ENST00000313400 / NM_001365069.1; = p.E556* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 35/290 reads (12%) | called by muse, mutect2, varscan2
- BCL9 | c.3087C>G p.I1029M | Missense Mutation (SNP) | VAF 34/664 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CALB1 | c.367C>A p.L123I | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CAMSAP2 | c.2412G>C p.K804N (on ENST00000236925 / NM_001297707.2; = p.K793N on NM_203459.3) | Missense Mutation (SNP) | VAF 33/283 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- CASP10 | c.1163G>C p.R388T (on ENST00000272879 / NM_032974.5; = p.R345T on NM_001230.5) | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- CCT6B | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- CD180 | c.43T>C p.S15P | Missense Mutation (SNP) | VAF 43/331 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- CDK5R2 | c.764C>A p.A255D | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.042); called by muse, mutect2
- CILP | c.2770T>A p.Y924N | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CNTN5 | c.2843T>A p.F948Y | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2
- COL5A2 | c.3844A>G p.M1282V | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CPVL | c.625T>C p.Y209H | Missense Mutation (SNP) | VAF 128/404 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CSMD3 | c.10320del p.G3441Afs*4 (on ENST00000297405 / NM_001363185.1; = p.G3272Afs*4 on NM_052900.3) | Frame Shift Del (DEL) | VAF 194/529 reads (37%) | called by mutect2, varscan2
- CTNNA1 | c.553G>C p.D185H | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.709); called by mutect2, varscan2
- CYTH2 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); called by muse, mutect2
- DGKH | c.2906_2908del p.K969_P970delinsT | In Frame Del (DEL) | VAF 49/291 reads (17%) | called by mutect2, pindel, varscan2
- EIF2AK1 | c.1176G>T p.W392C | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ENPP2 | c.1059C>A p.N353K (on ENST00000075322 / NM_001040092.3; = p.N405K on NM_006209.5) | Missense Mutation (SNP) | VAF 60/670 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- FOXK1 | c.597C>G p.I199M | Missense Mutation (SNP) | VAF 16/552 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- HTR3C | c.234G>A p.V78= | Splice Region (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2, varscan2
- HTR3C | c.234+1G>T p.X78_splice | Splice Site (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2, varscan2
- IDH3B | c.1108A>G p.T370A | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ISLR2 | c.1028C>A p.P343H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITIH5 | c.1072G>T p.G358W | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITIH5 | c.1071T>A p.D357E | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- KCNK2 | c.711T>G p.F237L (on ENST00000444842 / NM_001017425.3; = p.F222L on NM_014217.4) | Missense Mutation (SNP) | VAF 50/408 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); called by muse, varscan2
- KDM3B | c.4025C>A p.S1342* | Nonsense Mutation (SNP) | VAF 9/185 reads (5%) | called by muse, mutect2
- KLHL10 | c.847_874del p.L283Sfs*28 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | called by mutect2, pindel
- KMT5B | c.719A>G p.N240S | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.234); called by muse, mutect2
- KPNA4 | c.557-2A>T p.X186_splice | Splice Site (SNP) | VAF 20/124 reads (16%) | called by muse, mutect2, varscan2
- KRT75 | c.878C>A p.S293Y | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- LGALS9 | c.613G>T p.G205* (on ENST00000395473 / NM_009587.3; = p.G173* on NM_002308.4) | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- LRMDA | c.77G>A p.S26N | Missense Mutation (SNP) | VAF 29/370 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.01); called by muse, mutect2
- LRP1B | c.10687G>T p.G3563C | Missense Mutation (SNP) | VAF 64/315 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LTBP1 | c.4814A>T p.D1605V (on ENST00000404816 / NM_206943.4; = p.D1279V on NM_000627.4) | Missense Mutation (SNP) | VAF 50/335 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.081); called by muse, varscan2
- LZTR1 | c.1803C>G p.F601L | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MATR3 | c.557G>A p.R186K | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- MS4A7 | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MUC16 | c.4094C>A p.S1365Y | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- MYZAP | c.1163T>C p.I388T | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NAV3 | c.4561G>T p.A1521S | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NKAPL | c.580T>A p.S194T | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- NRG3 | c.635T>A p.V212E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, varscan2
- OR2V2 | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 54/476 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4C46 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 38/314 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- OR52A5 | c.614T>G p.V205G | Missense Mutation (SNP) | VAF 39/296 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PKHD1L1 | c.4493T>G p.V1498G | Missense Mutation (SNP) | VAF 28/832 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2
- PTPN11 | c.1615G>C p.G539R | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- PTPRA | c.559T>A p.S187T | Missense Mutation (SNP) | VAF 51/352 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PTPRA | c.602-1G>A p.X201_splice | Splice Site (SNP) | VAF 24/168 reads (14%) | called by muse, mutect2, varscan2
- RARB | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 42/428 reads (10%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2
- RERE | c.4439T>G p.L1480R | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RREB1 | c.1282C>G p.P428A | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- SCN4A | c.2792C>A p.S931Y | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2
- SEMA6C | c.320A>T p.D107V | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- SERPINA3 | c.275A>G p.H92R | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINB3 | c.648C>A p.Y216* | Nonsense Mutation (SNP) | VAF 13/131 reads (10%) | called by muse, mutect2
- SLC17A3 | c.1022del p.L341* | Frame Shift Del (DEL) | VAF 102/584 reads (17%) | called by mutect2, varscan2
- SLC22A12 | c.648C>A p.N216K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.175); called by mutect2, varscan2
- SLC34A1 | c.840G>T p.Q280H | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SLC47A2 | c.1045T>A p.C349S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- STK17B | c.1040G>T p.S347I | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBX18 | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM202 | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- TRAF5 | c.284A>C p.K95T | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRIM23 | c.71C>G p.A24G | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2
- TSSK1B | c.928A>T p.T310S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTLL3 | c.2649G>C p.K883N | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.101925G>T p.M33975I (on ENST00000591111; = p.M26551I on NM_003319.4) | Missense Mutation (SNP) | VAF 14/180 reads (8%) | PolyPhen benign (0.047); called by muse, mutect2
- UFL1 | c.2129C>T p.P710L | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VN1R2 | c.265G>T p.G89W | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2
- XYLT1 | c.1814A>C p.N605T | Missense Mutation (SNP) | VAF 54/550 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.114); called by muse, mutect2
- YTHDC1 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2, varscan2
- ZFP14 | c.1581G>C p.Q527H | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.884); called by muse, mutect2
- ZNF540 | c.720G>C p.E240D | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2
- ABCG2 | c.1083C>A p.I361= | Silent (SNP) | VAF 40/432 reads (9%) | called by muse, mutect2
- AOX1 | c.366G>A p.V122= | Silent (SNP) | VAF 16/169 reads (9%) | called by muse, mutect2, varscan2
- ARAP3 | c.3255C>T p.I1085= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as rs765404577, COSV53348705; called by muse, mutect2, varscan2
- ASPM | c.4305G>A p.K1435= | Silent (SNP) | VAF 7/99 reads (7%) | called by muse, mutect2
- BCL11A | c.1101C>T p.G367= (on ENST00000335712 / NM_001365609.1; = p.G401= on NM_018014.4) | Silent (SNP) | VAF 10/171 reads (6%) | catalogued as COSV59632641; called by muse, mutect2
- CCDC40 | c.3343C>A p.R1115= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV56408390; called by muse, mutect2, varscan2
- CDH2 | c.330G>A p.E110= | Silent (SNP) | VAF 100/813 reads (12%) | called by muse, mutect2, varscan2
- CR2 | c.2379C>T p.V793= | Silent (SNP) | VAF 24/276 reads (9%) | called by muse, mutect2
- CRACD | c.2754G>A p.R918= | Silent (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- CREB5 | c.852G>A p.L284= (on ENST00000357727 / NM_182898.4; = p.L277= on NM_004904.3) | Silent (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
- CWC15 | c.237A>C p.P79= | Silent (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- DOCK3 | c.5205G>A p.S1735= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs369636952; called by muse, mutect2, varscan2
- DPPA2 | c.438T>C p.C146= | Silent (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- EPHA8 | c.2616C>T p.L872= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs371208175; called by muse, mutect2, varscan2
- FOXF2 | c.513C>T p.G171= | Silent (SNP) | VAF 22/141 reads (16%) | catalogued as rs766061769; called by muse, mutect2, varscan2
- IGKV1-12 | c.40C>T p.L14= | Silent (SNP) | VAF 112/1118 reads (10%) | called by muse, mutect2, varscan2
- KRTAP10-8 | c.153C>T p.C51= | Silent (SNP) | VAF 54/192 reads (28%) | catalogued as rs782142098; called by muse, mutect2, varscan2
- LCE1C | c.30C>T p.C10= | Silent (SNP) | VAF 9/144 reads (6%) | catalogued as COSV100908486; called by muse, mutect2
- MAGI2 | c.3006C>T p.V1002= | Silent (SNP) | VAF 58/230 reads (25%) | called by muse, mutect2, varscan2
- MN1 | c.3891C>T p.S1297= | Silent (SNP) | VAF 40/131 reads (31%) | catalogued as rs1178901102, COSV56556257; called by muse, mutect2, varscan2
- MYO10 | c.33C>T p.V11= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as rs1399532470; called by muse, mutect2
- MYO1A | c.2157G>A p.L719= | Silent (SNP) | VAF 27/308 reads (9%) | catalogued as rs758170198, COSV100271336; called by muse, mutect2
- NCKAP5 | c.5400G>A p.G1800= | Silent (SNP) | VAF 21/179 reads (12%) | catalogued as rs781151641; called by muse, mutect2, varscan2
- NLRP3 | c.282A>C p.S94= | Silent (SNP) | VAF 65/336 reads (19%) | called by muse, mutect2, varscan2
- OR10A6 | c.196T>C p.L66= | Silent (SNP) | VAF 27/524 reads (5%) | catalogued as COSV59164986; called by muse, mutect2
- OR1C1 | c.825C>A p.T275= | Silent (SNP) | VAF 95/360 reads (26%) | called by muse, mutect2, varscan2
- OR4C13 | c.720C>A p.S240= | Silent (SNP) | VAF 97/477 reads (20%) | catalogued as rs782707423, COSV73648769; called by muse, mutect2, varscan2
- OR4C6 | c.351C>T p.A117= | Silent (SNP) | VAF 45/293 reads (15%) | catalogued as rs762154661; called by muse, mutect2, varscan2
- OR4D10 | c.843G>T p.L281= | Silent (SNP) | VAF 42/202 reads (21%) | called by muse, mutect2, varscan2
- P2RY1 | c.243G>A p.K81= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as rs771419503; called by muse, mutect2, varscan2
- PMFBP1 | c.2577A>G p.K859= (on ENST00000537465; = p.K854= on NM_031293.3) | Silent (SNP) | VAF 50/319 reads (16%) | called by muse, mutect2, varscan2
- PRDM9 | c.1563T>A p.I521= | Silent (SNP) | VAF 108/376 reads (29%) | called by muse, varscan2
- RNF144A | c.564C>T p.C188= | Silent (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2
- SELENOV | c.1005T>A p.I335= | Silent (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- SI | c.2091C>T p.P697= | Silent (SNP) | VAF 145/644 reads (23%) | catalogued as COSV100015477; called by muse, mutect2, varscan2
- SLC26A7 | c.420T>C p.F140= | Silent (SNP) | VAF 30/266 reads (11%) | catalogued as rs192849251; called by muse, mutect2, varscan2
- SLC6A2 | c.1227C>T p.F409= | Silent (SNP) | VAF 56/411 reads (14%) | catalogued as rs149035289; called by muse, mutect2, varscan2
- SLIT3 | c.909C>A p.A303= | Silent (SNP) | VAF 41/317 reads (13%) | catalogued as COSV100269727; called by muse, mutect2, varscan2
- SMOC1 | c.273C>T p.G91= | Silent (SNP) | VAF 61/423 reads (14%) | called by muse, mutect2, varscan2
- STX1B | c.421C>A p.R141= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs747003382; called by muse, mutect2, varscan2
- THNSL1 | c.864C>T p.Y288= | Silent (SNP) | VAF 23/158 reads (15%) | catalogued as rs150015345; called by muse, mutect2, varscan2
- TRPS1 | c.2031G>C p.V677= (on ENST00000220888 / NM_001330599.2; = p.V690= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/153 reads (15%) | called by muse, mutect2, varscan2
- UNC13C | c.5175G>A p.E1725= | Silent (SNP) | VAF 21/185 reads (11%) | called by muse, mutect2, varscan2
- USP34 | c.1339C>T p.L447= | Silent (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- ZGRF1 | c.2613A>C p.P871= | Silent (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- LEKR1 | c.*826C>A | 3'UTR (SNP) | VAF 15/101 reads (15%) | catalogued as COSV62961333; called by muse, mutect2, varscan2
- TTN | c.10360+1185A>G | Intron (SNP) | VAF 66/727 reads (9%) | called by muse, mutect2
